Gene-level copy-number profile of tumor specimen TCGA-E6-A8L9-01A from TCGA case TCGA-E6-A8L9, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 61.1 years (22,333 days).
Specimen TCGA-E6-A8L9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.b42799cc-b938-4660-bf60-f6963f156736.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-E6-A8L9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a490ed57-ef64-450c-89ea-89db5b61b9dc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 9; copy number 2: 19,715; copy number 3: 16,767; copy number 4: 19,461; copy number 5: 1,647; copy number 6: 1,147; copy number 7: 533; copy number 8: 320; copy number 9: 102; copy number 10: 30; copy number 11: 35; copy number 13: 31; copy number 14: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-E6-A8L9-01A-21D-A37M-01): tumor purity 0.73, ploidy 3.2, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:60,487,713–60,548,813, 1 gene (within-gene range 0–2): PART1.
- chr5:60,546,219–60,844,274, 6 genes (within-gene range 0–2): AC016591.1, DEPDC1B, CAB39P1, AC109133.1, KRT8P31, ELOVL7.
- chr5:163,039,291–163,039,599, 1 gene: MRPL57P6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,804 genes in 117 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,895,761–11,537,551, 23 genes, copy number 5: HSPE1P24, C1orf127, CFL1P6, TARDBP, AL109811.3, MASP2, AL109811.2, SRM, EXOSC10, AL109811.1, EXOSC10-AS1, MTOR, MTOR-AS1, RNU6-537P, ANGPTL7, RNU6-291P, RPL39P6, UBIAD1, UBE2V2P3, AL031291.1, MTCYBP45, DISP3, AL590989.1.
- chr1:31,506,226–33,512,743, 84 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:53,459,399–54,225,464, 23 genes, copy number 5–6: DMRTB1, GLIS1, RNU7-95P, NDC1, AL049745.1, AL049745.2, YIPF1, DIO1, HSPB11, LRRC42, HNRNPA3P12, LDLRAD1, TMEM59, AL353898.3, TCEANC2, MIR4781, AL353898.1, AL353898.2, AL357673.1, CDCP2, AL357673.2, CYB5RL, MRPL37.
- chr1:202,724,495–205,602,918, 100 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:211,476,522–212,626,775, 40 genes, copy number 7: RD3, AC105275.1, SLC30A1, AC105275.2, AL356310.1, LINC01693, NEK2, FDPSP8, AC096637.2, AC096637.1, LPGAT1, RN7SL344P, Y_RNA, LPGAT1-AS1, AC092814.2, INTS7, AC092814.1, DTL, RPL21P28, MIR3122, RN7SKP98, AL606468.1, LINC02608, PPP2R5A, AL360091.2, AL360091.3, RPL23AP18, SNORA16B, AL360091.1, PACC1, AC092803.3, NENF, LINC02771, AC092803.2, LINC01740, AC092803.1, AC092803.4, ATF3, AL590648.2, FAM71A.
- chr2:38,814–6,918,734, 98 genes, copy number 5 (broad region; genes not listed).
- chr2:7,141,227–43,596,046, 617 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr2:83,522,814–86,338,083, 73 genes, copy number 6–10 (within-gene range 4–10) (broad region; genes not listed).
- chr2:230,203,110–231,173,116, 28 genes, copy number 6 (within-gene range 4–6): SP140, SP140L, AC009949.1, SP100, RN7SL834P, HMGB1P3, AC010149.1, TPM3P8, AC010149.2, RNU6-451P, LINC01907, CAB39, BANF1P3, RNU6-268P, AC012507.2, ITM2C, GCSIR, GPR55, AC012507.1, AC012507.3, COX20P2, SPATA3-AS1, SPATA3, C2orf72, AC009407.1, PSMD1, HTR2B, RNU1-93P.
- chr2:233,545,482–234,497,081, 37 genes, copy number 6: PPFIA1P1, UGT1A12P, UGT1A11P, UGT1A8, UGT1A10, UGT1A13P, UGT1A9, UGT1A7, UGT1A6, AC114812.2, UGT1A5, UGT1A4, RPL17P11, UGT1A3, AC114812.3, DNAJB3, UGT1A2P, AC114812.4, AC114812.1, UGT1A1, MROH2A, HJURP, MSL3P1, AC005538.2, TRPM8, AC005538.1, AC005538.3, SPP2, AC006037.2, AC006037.1, AC122134.1, RPS20P12, AC097713.2, AC097713.1, LINC01891, HSPE1P9, ARL4C.
- chr3:50,088,919–52,897,562, 127 genes, copy number 5 (broad region; genes not listed).
- chr3:72,504,806–73,648,807, 24 genes, copy number 6 (within-gene range 4–6): AC104435.2, RNU1-62P, AC104435.1, RNA5SP136, AC097369.4, SHQ1, AC134050.1, PSMD12P1, LAPTM4BP2, GXYLT2, Metazoa_SRP, FTH1P23, PPP4R2, RNU7-19P, EBLN2, RNU6-557P, RNU2-64P, CCDC75P1, RNU6-1270P, PDZRN3, RNU7-119P, PDZRN3-AS1, AC117489.1, AC108725.1.
- chr4:2,234,251–3,271,738, 28 genes, copy number 5: COX6B1P5, MXD4, MIR4800, ZFYVE28, AL158068.2, RN7SL589P, AL158068.1, CFAP99, RNF4, AL645924.1, AL645924.2, FAM193A, CR545473.1, Y_RNA, TNIP2, SH3BP2, ADD1, AL121750.1, MFSD10, NOP14-AS1, NOP14, GRK4, HTT, RNU6-204P, HTT-AS, AL390065.2, AL390065.1, MSANTD1.
- chr7:131,493,964–135,317,752, 52 genes, copy number 6 (within-gene range 3–6): AC008264.2, PODXL, AC008264.1, EEF1B2P6, AC093106.1, AC093106.2, NDUFB9P2, CAPZA1P4, AC009518.2, AC009518.1, AC105443.1, PLXNA4, AC018643.1, AC011625.1, FLJ40288, AC009365.1, AC009365.2, CHCHD3, AC009365.3, AC008038.1, MIR3654, RNU6-92P, ST13P7, EXOC4, MIR6133, AC083875.1, COX5BP3, RPS3AP27, LRGUK, AC008154.2, SLC35B4, AC008154.1, AC009275.1, AKR1B1, AKR1B10, AKR1B15, BPGM, AC009276.1, TUBB3P2, CALD1, AC083870.1, AGBL3, CYREN, RNF14P4, TMEM140, AC083862.1, AC083862.2, WDR91, AC009542.1, MIR6509, STRA8, SLC23A4P.
- chr7:150,991,017–151,520,120, 32 genes, copy number 5: NOS3, ATG9B, ABCB8, AC010973.1, ASIC3, CDK5, SLC4A2, AC010973.3, AC010973.2, FASTK, TMUB1, AGAP3, GBX1, ASB10, IQCA1L, H2BE1, ABCF2-H2BE1, ABCF2, CHPF2, MIR671, SMARCD3, AC021097.1, AC005486.1, NUB1, WDR86, WDR86-AS1, AC005996.1, CRYGN, MIR3907, RN7SL76P, RHEB, ETF1P2.
- chr8:22,024,125–23,000,000, 39 genes, copy number 6 (within-gene range 4–6): NPM2, FGF17, DMTN, FAM160B2, NUDT18, HR, REEP4, LGI3, SFTPC, BMP1, AC105206.1, AC105206.3, PHYHIP, MIR320A, POLR3D, AC105206.2, PIWIL2, SLC39A14, AC105910.1, RNU6-336P, PPP3CC, AC087854.1, BTF3P3, SORBS3, AC037459.4, AC037459.3, PDLIM2, AC037459.1, C8orf58, CCAR2, AC037459.2, BIN3, AC105046.1, EGR3, AC055854.1, AC105046.2, PEBP4, AC037441.1, AC037441.2.
- chr8:37,784,191–40,016,391, 64 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:57,341,021–60,664,530, 43 genes, copy number 7–9: AC068075.1, RPL30P10, AC068075.2, AC090796.1, AC104051.1, AC104051.2, LINC01602, AC012103.1, FAM110B, AC104350.1, AC027698.1, RPL26P26, AC092819.3, AC092819.1, AC092819.2, UBXN2B, AC009927.1, CYP7A1, PPIAP85, SDCBP, NSMAF, AC068522.1, TOX, RNU4-50P, AC105150.1, AC090152.1, AC087698.1, RNA5SP267, AC087664.3, AC087664.1, AC087664.2, AC107934.1, AC107934.2, AC022709.1, AC021393.1, SLC2A13P1, CA8, LINC01301, PDCL3P1, RAB2A, AC068389.3, AC068389.1, AC068389.2.
- chr9:12,685,439–24,088,051, 177 genes, copy number 5 (broad region; genes not listed).
- chr9:25,579,657–29,318,952, 40 genes, copy number 5: AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1.
- chr9:120,751,978–122,331,337, 31 genes, copy number 5: FBXW2, B3GNT10, AL161911.1, PSMD5, CUTALP, PHF19, TRAF1, C5, CNTRL, RAB14, RN7SL181P, GSN, AL513122.1, AL513122.2, GSN-AS1, STOM, AL359644.1, GGTA1, RN7SL187P, HMGB1P37, DAB2IP, AL357936.1, AL596244.1, TTLL11, TTLL11-IT1, MIR4478, NDUFA8, MORN5, LHX6, RBM18, MRRF.
- chr9:123,109,494–124,877,733, 33 genes, copy number 5–8: MIR600HG, STRBP, MIR600, CRB2, DENND1A, MIR601, MIR7150, AL445489.1, AL390774.2, AL390774.1, PIGFP2, LHX2, AC006450.3, AC006450.1, AC006450.2, NEK6, AL162724.2, AL162724.1, PSMB7, ADGRD2, NR5A1, AL354979.1, NR6A1, AL669818.1, RN7SL302P, MIR181A2HG, MIR181A2, MIR181B2, AL354928.1, OLFML2A, WDR38, RPL35, ARPC5L.
- chr10:86,264,694–87,191,465, 32 genes, copy number 7 (within-gene range 3–7): MIR346, AL844892.2, AL844892.1, WAPL, RNU6-780P, AL731569.1, RPL7AP8, OPN4, LDB3, AC067750.1, BMPR1A, RPAP2P1, RNU1-19P, MMRN2, AC025268.1, SNCG, ADIRF-AS1, ADIRF, AL136982.7, AGAP11, BMS1P3, AL136982.1, AL136982.6, AL136982.4, AL136982.2, FAM25A, AL136982.5, RNU6-529P, GLUD1, SHLD2, AL136982.3, RN7SL733P.
- chr11:65,213,840–65,900,573, 57 genes, copy number 6 (within-gene range 4–6): SLC22A20P, AP000944.6, POLA2, AP000944.5, AP000944.7, CDC42EP2, DPF2, TIGD3, AP000944.1, SLC25A45, FRMD8, NEAT1, AP000944.4, AP000944.3, AP000944.2, MIR612, AP000769.4, AP000769.1, LINC02736, AP000769.6, MALAT1, AP000769.2, AP000769.5, AP000769.3, SNRPGP19, SCYL1, LTBP3, AP001362.1, ZNRD2-AS1, ZNRD2, FAM89B, EHBP1L1, KCNK7, MAP3K11, PCNX3, MIR4690, SIPA1, MIR4489, RELA, RELA-DT, RN7SL309P, KAT5, RNASEH2C, KRT8P26, AP001266.2, AP5B1, OVOL1, OVOL1-AS1, AP001266.1, CFL1, SNX32, MUS81, EFEMP2, CTSW, FIBP, CCDC85B, FOSL1.
- chr12:112,160,188–114,684,175, 53 genes, copy number 6 (within-gene range 4–6): HECTD4, MIR6861, AC004217.1, RN7SKP71, RPL7AP60, AC004217.2, RPL6, PTPN11, RPH3A, MIR1302-1, OAS1, AC004551.1, OAS3, OAS2, IMMP1LP2, RPS15AP32, DTX1, RASAL1, CFAP73, Y_RNA, DDX54, MIR7106, Y_RNA, RITA1, AC089999.1, IQCD, TPCN1, AC089999.2, MIR6762, SLC8B1, PLBD2, SDS, SDSL, LHX5, LHX5-AS1, LINC01234, DYNLL1P4, RBM19, AC009731.1, AC073863.1, AC010183.1, AC010183.2, HAUS8P1, GLULP5, LINC02459, TBX5, TBX5-AS1, RN7SKP216, AC069240.1, OSTF1P1, AC010177.1, Y_RNA, TBX3.
- chr12:119,959,424–120,761,592, 50 genes, copy number 6: RPL35AP30, BICDL1, Metazoa_SRP, AC004812.1, RAB35, AC004812.2, GCN1, MIR4498, RPLP0, PXN-AS1, PXN, AC004263.2, AC004263.1, RPS20P31, NME2P1, RNU4-2, RNU4-1, SIRT4, RNU6-1088P, PLA2G1B, MSI1, RPS27P25, AC003982.1, COX6A1, AL021546.1, TRIAP1, GATC, RPL31P52, SRSF9, DYNLL1, NRAV, AC063943.1, COQ5, Y_RNA, RPL29P24, RNF10, AC063943.2, POP5, RPL11P5, AC125616.1, CABP1, MLEC, AC069234.2, AC069234.5, AC069234.4, UNC119B, AC069234.3, MIR4700, ACADS, AC069234.1.
- chr14:22,066,016–22,505,167, 64 genes, copy number 5 (broad region; genes not listed).
- chr16:71,859,680–75,761,872, 106 genes, copy number 5–9 (within-gene range 3–9) (broad region; genes not listed).
- chr17:1,934,677–2,723,947, 50 genes, copy number 7: RTN4RL1, AC099684.2, AC099684.1, AC099684.3, DPH1, AC090617.10, OVCA2, AC090617.3, AC090617.5, MIR132, MIR212, HIC1, SMG6, AC090617.9, AC090617.4, AC090617.6, AC090617.8, AC090617.7, MCUR1P1, RN7SL624P, AC090617.2, AC090617.1, AL450226.1, SMG6-IT1, AL450226.2, SRR, HNRNPA1P16, TSR1, SNORD91B, SNORD91A, SGSM2, AC006435.3, AC006435.2, MNT, AC006435.1, METTL16, AC006435.4, AC006435.5, RN7SL33P, EIF4A1P9, PAFAH1B1, SAMD11P1, AC015799.1, RN7SL608P, AC005696.2, AC005696.3, CLUH, MIR6776, AC005696.1, AC005696.4.
- chr17:28,719,985–29,294,148, 42 genes, copy number 7–13 (within-gene range 2–13): RPL23A, SNORD42B, AC010761.1, SNORD4A, SNORD42A, SNORD4B, TLCD1, NEK8, AC010761.6, AC010761.2, TRAF4, AC010761.4, AC010761.5, FAM222B, RPL31P58, Y_RNA, AC024267.2, ERAL1, AC024267.1, MIR451A, MIR451B, MIR144, MIR4732, FLOT2, AC024267.3, AC024267.6, DHRS13, PHF12, AC024267.4, AC024267.5, PIPOX, SEZ6, AC024619.2, AC024619.1, AC024619.4, MYO18A, TIAF1, AC024619.3, AC005412.1, TWF1P1, CRYBA1, NUFIP2.
- chr17:39,546,104–40,527,002, 54 genes, copy number 6: RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867, WIPF2, CDC6, RARA, AC080112.4, RARA-AS1, AC080112.3, GJD3, AC080112.1, PPIAP54, RNA5SP441, AC080112.2, TOP2A, Y_RNA, RPL23AP75, IGFBP4, AC018629.1, TNS4, AC004585.1.
- chr18:1,509,022–4,455,307, 55 genes, copy number 7 (within-gene range 4–7): AP005262.1, AC019183.1, AP005057.1, AP005230.1, AIDAP3, AP005136.4, METTL4, AP005136.1, AP005136.3, AP005136.2, NDC80, KATNBL1P3, Y_RNA, RNU6-340P, CBX3P2, SMCHD1, AP001011.1, Y_RNA, EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66, DLGAP1-AS5.
- chr18:20,946,906–27,247,188, 126 genes, copy number 5–9 (broad region; genes not listed).
- chr18:75,642,494–78,036,845, 51 genes, copy number 5: AC090338.1, LINC01898, AC021506.1, AC021506.2, AC090457.1, AC011095.1, AC103808.6, LINC01893, AC103808.2, AC103808.4, AC103808.3, AC103808.1, AC103808.5, ZNF516, AC009716.1, AC009716.2, AC018413.1, ZNF516-DT, LINC00683, AC034110.1, LINC01927, LINC01879, ARL2BPP1, CCND3P2, AC139085.1, ZNF236-DT, RNU6-346P, AC027575.2, ZNF236, RPL26P35, Metazoa_SRP, AC027575.1, AC093330.1, MBP, AC093330.2, AC093330.3, AC018529.1, AC018529.3, AC018529.2, AC100863.1, GALR1, AC124254.2, AC124254.1, BDP1P, AC123786.1, AC123786.2, AC123786.3, RNA5SP461, LINC01029, AC134978.1, RNU6-655P.
- chr19:16,888,999–17,895,174, 59 genes, copy number 7–11: F2RL3, CPAMD8, RN7SL835P, RN7SL823P, AC020908.2, HAUS8, AC020908.1, MYO9B, AC020908.3, AC020913.1, AC020913.3, AC020913.2, USE1, OCEL1, NR2F6, AC010646.1, USHBP1, BABAM1, AC010463.1, ANKLE1, ABHD8, MRPL34, AC010463.3, DDA1, ANO8, GTPBP3, PLVAP, AC010463.2, CCDC194, BST2, BISPR, MVB12A, AC010319.4, AC010319.1, AC010319.3, TMEM221, AC010319.2, AC010319.5, NXNL1, SLC27A1, AC010618.3, PGLS, AC010618.2, NIBAN3, COLGALT1, AC010618.1, UNC13A, AC008761.2, AC008761.3, MAP1S, AC008761.1, FCHO1, B3GNT3, INSL3, JAK3, RPL18A, SNORA68, AC005796.1, SLC5A5.
- chr20:31,303,212–32,101,856, 42 genes, copy number 6: DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK.
- chr20:33,965,162–54,070,594, 511 genes, copy number 6–9 (broad region; genes not listed).
- chr20:57,648,392–59,259,113, 43 genes, copy number 5 (within-gene range 4–5): PMEPA1, NKILA, AL162291.1, AL354984.1, LINC01742, AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, AL109840.2, AL109840.1, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831.
- chr21:43,159,066–44,262,216, 39 genes, copy number 5 (within-gene range 3–5): AP001631.1, CRYAA, LINC00322, LINC01679, AP001046.1, SIK1, LINC00319, LINC00313, AP001048.1, HSF2BP, RPL31P1, H2BS1, MIR6070, RRP1B, PDXK, AP001052.1, AP001053.1, CSTB, TMEM97P1, RRP1, AATBC, MYL6P1, AGPAT3, RNU6-859P, AP001054.1, RNU6-1150P, TRAPPC10, H2AZP1, PWP2, GATD3A, LINC01678, AP001056.2, AP001056.1, AP001057.1, ICOSLG, AP001059.2, AP001059.1, DNMT3L, DNMT3L-AS1.
- chr22:37,570,248–38,216,507, 39 genes, copy number 8 (within-gene range 4–8): LGALS2, Metazoa_SRP, GGA1, SH3BP1, Z83844.2, PDXP-DT, PDXP, RN7SL385P, LGALS1, NOL12, Z83844.1, TRIOBP, H1-0, GCAT, GALR3, ANKRD54, MIR658, MIR659, EIF3L, AL022311.1, RNU6-900P, MICALL1, AL031587.5, C22orf23, AL031587.3, POLR2F, MIR6820, SOX10, MIR4534, AL031587.1, AL031587.4, PICK1, AL031587.2, SLC16A8, BAIAP2L2, AL022322.1, PLA2G6, AL022322.2, MAFF.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
